Somatic mutation profile of tumor specimen MMRF_2506_1_BM_CD138pos (aliquot MMRF_2506_1_BM_CD138pos_T1_KHS5U_K15131) from MMRF case MMRF_2506, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 81.4 years (29,719 days).
Specimen MMRF_2506_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40b170b7-c600-4c18-8b6f-e68e0317b2c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2506_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2506_1_PB_Whole_C3_KHS5U_K15130; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b2b3959-6181-43da-983c-cc7baae1c813

The open-access MAF lists 109 somatic variants for this specimen: 39 protein-altering or splice-affecting, 14 silent, 56 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 32, Missense Mutation 31, Silent 14, Intron 14, Splice Site 4, 5'UTR 4, 5'Flank 3, Frame Shift Ins 3, RNA 2, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGK | c.976-1G>A p.X326_splice | Splice Site (SNP) | VAF 60/117 reads (51%) | catalogued as COSV100814561, COSV62594884; called by muse, mutect2, varscan2
- ARFGEF3 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs772861520; called by muse, mutect2, varscan2
- ARHGAP33 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 135/268 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV50168087; called by muse, mutect2, varscan2
- BTBD1 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 121/365 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1156606973; called by muse, mutect2, varscan2
- DSEL | c.449T>G p.V150G | Missense Mutation (SNP) | VAF 190/386 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV59489145; called by muse, mutect2, varscan2
- FAM222A | c.1021G>A p.V341I | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as rs767158144; called by muse, mutect2, varscan2
- HMCES | c.1024A>G p.K342E | Missense Mutation (SNP) | VAF 165/250 reads (66%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs558051897; called by muse, mutect2, varscan2
- IER3 | c.166C>G p.R56G | Missense Mutation (SNP) | VAF 77/171 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV99458207; called by muse, mutect2, varscan2
- IGKV2D-30 | c.196G>A p.G66S | Missense Mutation (SNP) | VAF 70/85 reads (82%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.557); catalogued as rs372840355; called by muse, mutect2, varscan2
- IGLV3-21 | c.290A>G p.E97G | Missense Mutation (SNP) | VAF 33/33 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as rs373184711; called by muse, varscan2
- IGSF9B | c.2378C>T p.P793L | Missense Mutation (SNP) | VAF 49/228 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs1329059136; called by muse, mutect2, varscan2
- MICU3 | c.1253A>G p.E418G | Missense Mutation (SNP) | VAF 22/22 reads (100%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.994); catalogued as rs775679044; called by muse, mutect2, varscan2
- POT1 | c.871G>T p.D291Y | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV62928859, COSV62933167; called by muse, mutect2, varscan2
- SLC1A1 | c.1508A>T p.Y503F | Missense Mutation (SNP) | VAF 94/575 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.358); catalogued as COSV99261585; called by muse, mutect2, varscan2
- SPPL2C | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 186/299 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs779097529, COSV61293954; called by muse, mutect2, varscan2
- ZNF408 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 178/625 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1381654753; called by muse, mutect2, varscan2
- ANKFN1 | c.1507T>A p.S503T | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- CBFB | c.207dup p.P70Sfs*13 | Frame Shift Ins (INS) | VAF 9/86 reads (10%) | called by mutect2, pindel, varscan2
- CNR1 | c.1311C>A p.N437K | Missense Mutation (SNP) | VAF 166/361 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- COPG1 | c.1287dup p.E430Rfs*49 | Frame Shift Ins (INS) | VAF 78/263 reads (30%) | called by mutect2, pindel, varscan2
- CWC22 | c.2033C>T p.S678L | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EXOC7 | c.866G>A p.G289E | Missense Mutation (SNP) | VAF 49/198 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- FOLH1B | n.1853-2A>T | Splice Site (SNP) | VAF 57/270 reads (21%) | called by muse, mutect2, varscan2
- GRK7 | c.1280G>A p.C427Y | Missense Mutation (SNP) | VAF 186/298 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- HDDC3 | c.169-17_176del p.X57_splice | Splice Site (DEL) | VAF 54/220 reads (25%) | called by mutect2, pindel
- HNRNPC | c.242A>G p.D81G | Missense Mutation (SNP) | VAF 67/130 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- IGLV3-21 | c.284G>T p.R95M | Missense Mutation (SNP) | VAF 36/36 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, varscan2
- LNPK | c.1146del p.A383Hfs*20 | Frame Shift Del (DEL) | VAF 100/265 reads (38%) | called by mutect2, pindel, varscan2
- MFSD6 | c.1663A>G p.I555V | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- MORC1 | c.2719G>A p.E907K | Missense Mutation (SNP) | VAF 56/188 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MPHOSPH10 | c.1664A>T p.K555M | Missense Mutation (SNP) | VAF 67/161 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MUC16 | c.35054A>T p.D11685V | Missense Mutation (SNP) | VAF 95/307 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- PIN1 | c.39G>C p.K13N | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- PRDM1 | c.2027T>G p.L676R | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RPS6KB2 | c.969+2T>C p.X323_splice | Splice Site (SNP) | VAF 279/384 reads (73%) | called by muse, mutect2, varscan2
- SAA2-SAA4 | c.495A>G p.I165M | Missense Mutation (SNP) | VAF 132/259 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC6A17 | c.1797C>A p.S599R | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- SRSF8 | c.337_338insCCGCG p.G113Afs*139 | Frame Shift Ins (INS) | VAF 15/92 reads (16%) | called by mutect2, pindel, varscan2
- UBTD1 | c.620C>A p.T207N | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- AGT | c.810C>A p.A270= | Silent (SNP) | VAF 104/235 reads (44%) | called by muse, mutect2, varscan2
- ANKRD33B | c.1299G>A p.A433= | Silent (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2, varscan2
- C17orf80 | c.438C>T p.T146= | Silent (SNP) | VAF 71/252 reads (28%) | catalogued as rs763252790, COSV52148761; called by muse, mutect2, varscan2
- CDHR5 | c.1467C>T p.S489= (on ENST00000358353 / NM_001171968.2; = p.S495= on NM_021924.5) | Silent (SNP) | VAF 140/483 reads (29%) | called by muse, mutect2, varscan2
- CSMD3 | c.1560C>T p.G520= (on ENST00000297405 / NM_001363185.1; = p.G416= on NM_052900.3) | Silent (SNP) | VAF 20/250 reads (8%) | catalogued as rs377399711, COSV52155977, COSV52234883; called by muse, mutect2
- DLGAP1 | c.456G>A p.S152= | Silent (SNP) | VAF 68/196 reads (35%) | called by muse, mutect2, varscan2
- HMGXB3 | c.3642C>T p.V1214= (on ENST00000613459; = p.V968= on NM_014983.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 73/138 reads (53%) | catalogued as rs757889225; called by muse, mutect2, varscan2
- IGLV3-21 | c.189G>A p.V63= | Silent (SNP) | VAF 56/56 reads (100%) | catalogued as rs375188340; called by muse, varscan2
- MAP1S | c.2121G>A p.P707= | Silent (SNP) | VAF 82/209 reads (39%) | catalogued as rs749037460; called by muse, mutect2, varscan2
- NKX2-4 | c.1029C>T p.V343= | Silent (SNP) | VAF 44/47 reads (94%) | catalogued as rs1200146115; called by muse, mutect2, varscan2
- OTOG | c.1554T>G p.G518= | Silent (SNP) | VAF 217/296 reads (73%) | called by muse, mutect2, varscan2
- PROM1 | c.204G>A p.P68= | Silent (SNP) | VAF 15/191 reads (8%) | catalogued as rs775249686; called by muse, mutect2
- RTN4RL1 | c.378G>A p.K126= | Silent (SNP) | VAF 103/269 reads (38%) | called by muse, mutect2, varscan2
- ZNF469 | c.6090C>T p.P2030= (on ENST00000437464; = p.P2058= on NM_001367624.2) | Silent (SNP) | VAF 86/115 reads (75%) | called by muse, mutect2, varscan2
- AC012485.1 | n.321C>T | RNA (SNP) | VAF 34/65 reads (52%) | called by muse, mutect2, varscan2
- ACAD11 | c.*118T>G | 3'UTR (SNP) | VAF 125/440 reads (28%) | called by muse, mutect2, varscan2
- ACTG1 | c.364-125G>A | Intron (SNP) | VAF 21/44 reads (48%) | called by muse, mutect2, varscan2
- ADAMTS17 | c.*856C>T | 3'UTR (SNP) | VAF 104/308 reads (34%) | catalogued as rs549608045; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADM | c.-128T>G | 5'UTR (SNP) | VAF 75/319 reads (24%) | called by muse, mutect2, varscan2
- ATG4B | c.*1330T>A | 3'UTR (SNP) | VAF 25/53 reads (47%) | called by muse, mutect2, varscan2
- ATG4B | c.*1331C>T | 3'UTR (SNP) | VAF 25/53 reads (47%) | called by muse, mutect2, varscan2
- ATG4C | c.*10C>A | 3'UTR (SNP) | VAF 91/198 reads (46%) | called by muse, mutect2, varscan2
- ATP6V0A1 | c.634-106T>A | Intron (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- CDK5 | c.313-157C>A | Intron (SNP) | VAF 20/27 reads (74%) | called by muse, mutect2, varscan2
- CGGBP1 | c.-23-437T>C | Intron (SNP) | VAF 115/169 reads (68%) | called by muse, mutect2, varscan2
- CYP27A1 | chr2:218781776 G>A | 5'Flank (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- DFFB | c.*1102T>A | 3'UTR (SNP) | VAF 34/62 reads (55%) | called by muse, mutect2, varscan2
- DUSP12 | c.*241A>T | 3'UTR (SNP) | VAF 6/12 reads (50%) | catalogued as rs1278829819; called by muse, varscan2
- DUSP22 | c.509-723G>A | Intron (SNP) | VAF 19/299 reads (6%) | called by muse, mutect2
- EEF1A1 | c.*1920dup | 3'UTR (INS) | VAF 19/55 reads (35%) | called by mutect2, pindel, varscan2
- EFS | c.*409A>T | 3'UTR (SNP) | VAF 34/90 reads (38%) | catalogued as rs552434831; called by muse, mutect2, varscan2
- EIF2S3 | c.*802A>C | 3'UTR (SNP) | VAF 172/174 reads (99%) | called by muse, mutect2, varscan2
- FAM13C | c.62+1335C>T | Intron (SNP) | VAF 93/221 reads (42%) | called by muse, mutect2, varscan2
- FAM71F2 | c.*1095A>G | 3'UTR (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- FBN1 | c.-151G>A | 5'UTR (SNP) | VAF 43/148 reads (29%) | called by muse, mutect2, varscan2
- FIBP | chr11:65883879 A>G | 3'Flank (SNP) | VAF 231/488 reads (47%) | called by muse, mutect2, varscan2
- GJB7 | c.*835_*836del | 3'UTR (DEL) | VAF 34/107 reads (32%) | called by mutect2, pindel, varscan2
- H2BC15 | chr6:27837899 C>A | 5'Flank (SNP) | VAF 24/365 reads (7%) | called by muse, mutect2
- HHIP | c.*2762A>G | 3'UTR (SNP) | VAF 29/54 reads (54%) | catalogued as rs548248475; called by muse, mutect2, varscan2
- IGFBP5 | c.*4086G>A | 3'UTR (SNP) | VAF 62/141 reads (44%) | catalogued as rs540907010; called by muse, mutect2, varscan2
- JPH3 | c.-156C>T | 5'UTR (SNP) | VAF 18/219 reads (8%) | catalogued as rs1567577293; called by muse, mutect2
- LHX5 | c.*333C>G | 3'UTR (SNP) | VAF 4/38 reads (11%) | catalogued as rs1335349856; called by muse, varscan2
- MDH1 | c.*49C>T | 3'UTR (SNP) | VAF 31/63 reads (49%) | catalogued as rs1802753; called by muse, mutect2, varscan2
- MXI1 | c.*538_*542del | 3'UTR (DEL) | VAF 10/65 reads (15%) | catalogued as rs965527517; called by pindel, varscan2
- NFASC | c.*4441G>A | 3'UTR (SNP) | VAF 47/89 reads (53%) | catalogued as rs529464796; called by muse, mutect2, varscan2
- NOVA1 | c.*828G>A | 3'UTR (SNP) | VAF 31/71 reads (44%) | called by muse, mutect2, varscan2
- OR7C1 | c.*6370G>A | 3'UTR (SNP) | VAF 87/144 reads (60%) | catalogued as rs768991948; called by muse, mutect2, varscan2
- PAICS | c.-51-53G>A | Intron (SNP) | VAF 23/78 reads (29%) | called by muse, mutect2, varscan2
- PALLD | c.*120T>C | 3'UTR (SNP) | VAF 27/356 reads (8%) | called by muse, mutect2
- PGAM5 | c.*1278A>G | 3'UTR (SNP) | VAF 21/49 reads (43%) | catalogued as rs1214432451; called by muse, mutect2, varscan2
- PMS2P3 | n.265G>A | RNA (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- PPM1L | c.*8304G>A | 3'UTR (SNP) | VAF 40/152 reads (26%) | called by muse, mutect2, varscan2
- RNU1-5P | chr1:16871846 C>G | 5'Flank (SNP) | VAF 74/177 reads (42%) | catalogued as rs1198697457; called by muse, mutect2, varscan2
- RPLP2 | c.-2+42G>A | Intron (SNP) | VAF 11/59 reads (19%) | called by muse, mutect2, varscan2
- RWDD3 | c.*330G>T | 3'UTR (SNP) | VAF 11/22 reads (50%) | called by muse, varscan2
- SELENOI | c.*3616_*3617del | 3'UTR (DEL) | VAF 61/158 reads (39%) | called by mutect2, pindel, varscan2
- SIRPB2 | c.859+375G>A | Intron (SNP) | VAF 60/62 reads (97%) | catalogued as rs755181882; called by muse, mutect2, varscan2
- SLC6A1 | c.1324-33A>G | Intron (SNP) | VAF 50/144 reads (35%) | called by mutect2, varscan2
- SP4 | c.*1599A>C | 3'UTR (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- SYDE2 | c.*1647A>C | 3'UTR (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2, varscan2
- TMC3 | c.600+38A>T | Intron (SNP) | VAF 86/259 reads (33%) | called by muse, mutect2, varscan2
- TMTC1 | c.*1665T>G | 3'UTR (SNP) | VAF 43/92 reads (47%) | called by muse, mutect2, varscan2
- TVP23C | c.12+72G>A | Intron (SNP) | VAF 12/18 reads (67%) | called by muse, mutect2
- VPS36 | c.*2602A>G | 3'UTR (SNP) | VAF 6/108 reads (6%) | called by muse, mutect2
- WDR36 | c.358+61A>C | Intron (SNP) | VAF 30/58 reads (52%) | called by muse, mutect2, varscan2
- WEE2 | c.-108G>A | 5'UTR (SNP) | VAF 23/44 reads (52%) | catalogued as rs564677092, COSV101285232; called by muse, mutect2, varscan2
- ZCCHC14 | c.*2124G>C | 3'UTR (SNP) | VAF 71/80 reads (89%) | called by muse, mutect2, varscan2
- ZNF311 | c.183+115A>G | Intron (SNP) | VAF 30/48 reads (63%) | called by muse, mutect2, varscan2
- ZNF516 | c.*2965G>A | 3'UTR (SNP) | VAF 51/128 reads (40%) | catalogued as rs769509655, COSV71586623; called by muse, mutect2, varscan2
- ZNF648 | c.*573G>T | 3'UTR (SNP) | VAF 28/80 reads (35%) | called by muse, mutect2, varscan2
